Somatic mutation profile of tumor specimen MMRF_1061_1_BM_CD138pos (aliquot MMRF_1061_1_BM_CD138pos_T2_KHS5U_L13422) from MMRF case MMRF_1061, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.3 years (25,691 days).
Specimen MMRF_1061_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40c5f37d-27f2-46ff-9913-c635093989ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1061_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1061_1_PB_Whole_C1_KHS5U_L13433; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b0cb328-0b4c-488e-ab85-d7f2ce64c9ce

The open-access MAF lists 80 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 15, Intron 10, Silent 10, 3'Flank 3, Splice Site 3, Frame Shift Del 2, Nonsense Mutation 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 92/95 reads (97%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC8 | c.1126C>T p.R376W (on ENST00000469044 / NM_001363941.2; = p.R362W on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1450402393, COSV100627688, COSV61769891; called by muse, mutect2, varscan2
- BCLAF3 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 119/218 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV61415396; called by muse, mutect2, varscan2
- CAMTA1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs966383954, COSV100345986; called by muse, mutect2, varscan2
- CHD2 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 31/56 reads (55%) | catalogued as CD129351; called by muse, mutect2, varscan2
- DLGAP2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1273654798; called by muse, mutect2, varscan2
- IGLV2-8 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs762944733; called by muse, varscan2
- ITGAM | c.1736C>T p.P579L (on ENST00000648685 / NM_001145808.2; = p.P578L on NM_000632.4) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54938574; called by muse, mutect2, varscan2
- MAP1B | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.411); catalogued as COSV57102960, COSV57104343; called by muse, mutect2, varscan2
- OR10G4 | c.682C>A p.R228S | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV57979339; called by muse, mutect2, varscan2
- OR4M1 | c.873G>C p.L291F | Missense Mutation (SNP) | VAF 49/1016 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV60061988; called by muse, mutect2
- OR4N2 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750788192, COSV60053250; called by muse, mutect2, varscan2
- RASGEF1C | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV63184275; called by muse, mutect2, varscan2
- SIGLEC10 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.168); catalogued as rs762968568; called by muse, mutect2, varscan2
- TTBK1 | c.2744G>A p.G915D | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as rs757208521, COSV52491899; called by muse, mutect2, varscan2
- AGPAT4 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ALK | c.2546dup p.Y849* | Nonsense Mutation (INS) | VAF 57/156 reads (37%) | called by mutect2, pindel, varscan2
- CCSER1 | c.1128T>G p.N376K | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPJ | c.1757A>G p.D586G | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DNAH11 | c.12722A>T p.D4241V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DYNC2H1 | c.3255_3256del p.K1087Nfs*2 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- EEF1A2 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EEF2 | c.118_122delinsTCAC p.V40Sfs*47 | Frame Shift Del (DEL) | VAF 61/170 reads (36%) | called by pindel, varscan2*
- FGD1 | c.2254C>T p.H752Y | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- GPR158 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HCFC1 | c.5396C>T p.P1799L | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.8678A>G p.K2893R | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LRIT1 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- MAGEB16 | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MCEE | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.6355G>C p.E2119Q | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MMP7 | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2
- PLCB3 | c.1992C>G p.F664L | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTN2 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 92/172 reads (53%) | called by muse, mutect2, varscan2
- SAMD9 | c.508A>T p.S170C | Missense Mutation (SNP) | VAF 125/242 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SETD1B | c.5263A>G p.I1755V | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- STARD9 | c.8684C>T p.S2895F | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STARD9 | c.11146G>A p.D3716N | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRIM24 | c.105T>G p.S35R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRPC1 | c.1561T>C p.S521P (on ENST00000476941 / NM_001251845.2; = p.S487P on NM_003304.4) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, varscan2
- UBL4A | c.474G>T p.*158Yext*19 | Nonstop Mutation (SNP) | VAF 119/251 reads (47%) | called by muse, mutect2, varscan2
- EOMES | c.765G>C p.L255= | Silent (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- FLVCR1 | c.624C>T p.C208= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- GABRG1 | c.30C>A p.S10= | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as COSV54950033, COSV54954460; called by muse, mutect2, varscan2
- GEMIN2 | c.696A>G p.S232= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.51C>T p.S17= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as rs560847585; called by muse, varscan2
- IGLV2-11 | c.135C>T p.S45= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs372058556; called by muse, varscan2
- KIFAP3 | c.1251A>G p.K417= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs1319169074; called by muse, mutect2, varscan2
- PLPPR4 | c.2196C>A p.G732= | Silent (SNP) | VAF 151/283 reads (53%) | called by muse, mutect2, varscan2
- SLC7A8 | c.561A>G p.Q187= | Silent (SNP) | VAF 161/303 reads (53%) | catalogued as COSV57553626; called by muse, mutect2, varscan2
- TBC1D10B | c.2364C>T p.P788= | Silent (SNP) | VAF 100/203 reads (49%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826238 C>A | 3'Flank (SNP) | VAF 98/223 reads (44%) | called by muse, mutect2, varscan2
- BBS7 | c.601+50G>C | Intron (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- BCL2 | c.-599C>T | 5'UTR (SNP) | VAF 92/200 reads (46%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*251G>T | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- COA8 | chr14:103590938 C>T | 3'Flank (SNP) | VAF 9/25 reads (36%) | catalogued as rs1013884053; called by muse, mutect2, varscan2
- DMRTC2 | c.817-72G>A | Intron (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- EPYC | c.*439G>A | 3'UTR (SNP) | VAF 25/68 reads (37%) | catalogued as rs578039046; called by muse, mutect2, varscan2
- L3MBTL1 | c.1285-498T>G | Intron (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- LIN28A | c.*165T>G | 3'UTR (SNP) | VAF 98/201 reads (49%) | called by muse, mutect2, varscan2
- LSM11 | c.*4221T>A | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- MTHFD1 | c.2280-239A>G | Intron (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- MUTYH | c.36+1948G>T | Intron (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- OR51L1 | c.*8C>A | 3'UTR (SNP) | VAF 91/187 reads (49%) | called by muse, mutect2, varscan2
- PIK3CD | c.*667G>A | 3'UTR (SNP) | VAF 10/88 reads (11%) | catalogued as rs1351059628; called by muse, mutect2, varscan2
- PPM1B | c.1135-293T>C | Intron (SNP) | VAF 85/188 reads (45%) | called by muse, mutect2, varscan2
- PTDSS1 | c.*3273T>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- RAD1 | chr5:34907604 T>G | 3'Flank (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- RASAL2 | c.*2519T>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as rs1558022408; called by muse, mutect2, varscan2
- RNF217 | c.*7564T>A | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs1263998280; called by muse, mutect2, varscan2
- SAMD4A | c.*918G>A | 3'UTR (SNP) | VAF 70/144 reads (49%) | called by muse, mutect2, varscan2
- SBF2 | c.*826A>G | 3'UTR (SNP) | VAF 70/118 reads (59%) | called by muse, mutect2, varscan2
- SEC16A | c.*1135C>T | 3'UTR (SNP) | VAF 38/94 reads (40%) | catalogued as rs756377182; called by muse, mutect2, varscan2
- SLC35B4 | c.*4526T>C | 3'UTR (SNP) | VAF 21/53 reads (40%) | catalogued as rs1337914581; called by muse, mutect2, varscan2
- SPAG16 | c.536+122G>A | Intron (SNP) | VAF 23/49 reads (47%) | catalogued as rs1364694803; called by muse, mutect2, varscan2
- SRD5A3 | c.*622C>T | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs951741748; called by muse, mutect2, varscan2
- TRPV4 | c.*407C>T | 3'UTR (SNP) | VAF 55/179 reads (31%) | called by muse, mutect2, varscan2
- TTC39C | c.985-737C>T | Intron (SNP) | VAF 41/83 reads (49%) | catalogued as rs967257932; called by muse, mutect2, varscan2
- TTN | c.10361-4755A>C | Intron (SNP) | VAF 230/474 reads (49%) | called by muse, mutect2, varscan2
- ZC4H2 | c.54-69A>T | Intron (SNP) | VAF 152/319 reads (48%) | called by muse, mutect2, varscan2
